Surgical pathology report (de-identified scan), TCGA case TCGA-BA-5555, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site UNC, specimen TCGA-BA-5555-01A (Primary Tumor).

[page 1 of 4]
Case Number :

Surgical Pathology Report

Diagnosis:

A: Right base of tongue, biopsy

- No tumor seen.

B: Left inferior pharyngeal margin, biopsy

- No tumor seen.

C: Right superior pharyngeal margin, biopsy

- No tumor seen.

D: Right neck soft tissue margin, biopsy

- No tumor seen.

E: Lymph node, right Level 2A, removal

- No tumor seen in four lymph nodes (0/4).

F: Lymph node, right supraclavicular, removal

- No tumor seen in two lymph nodes (0/2).

G: Lymph node, right Level 2, removal

- No tumor seen in four lymph nodes (0/4).

H: Lymph node, right neck, Level 3, removal

- No tumor seen in fourteen lymph nodes (0/14).

I: Lymph node, right neck, Level 4, removal

- No tumor seen in eight lymph nodes (0/8).

J: Lymph node, left Level 1B, removal

- No tumor seen in two lymph nodes (0/2).

K: Lymph node, left Level 2A and 3, removal

- Metastatic squamous cell carcinoma in 1 of 9 lymph nodes, size of metastasis 1.5 cm, no extranodal extension of tumor identified.

L: Lymph node, left Level 2B, removal

- No tumor seen in eleven lymph nodes (0/11).

M: Lymph node, left Level 3, removal

- No tumor seen in nine lymph nodes (0/9).

N: Lymph node, left Level 4, removal

- No tumor seen in five lymph nodes (0/5).

O: Larynx and thyroid, total laryngectomy/thyroidectomy and neck dissection

Tumor histologic type/subtype: squamous cell carcinoma

Histologic grade: moderately differentiated

Location of primary site: Tumor involves the right glottis and midline glottis, right aryepiglottic fold, and right pyriform sinus.

Size: 2.7 cm

Extent of invasion:

Angiolymphatic: not identified

Adjacent subsite: yes (see location section above)

Into/through cartilage: into the cricoid cartilage

Outside the larynx: no

In situ carcinoma: yes, overlying tumor

[page 2 of 4]
Surgical Margins: free of tumor

Lymph nodes: see specimen E-N above

Size of largest metastasis: 1.5 cm

Extra-capsular extension: not identified

Other significant findings: none

AJCC PATHOLOGIC TNM STAGE: pT3 pN1

NOTE: This pathologic stage assessment is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

P: Right base of tongue, resection

- No tumor seen.

Intraoperative Consult Diagnosis:

An intraoperative consultation was requested by Dr

FSA1: Right base of tongue, biopsy

- No tumor seen.

FSB1: Left inferior pharyngeal margin, biopsy

- No tumor seen.

FSC1: Right superior pharyngeal margin, biopsy

- No tumor seen.

FSD1: Right neck soft tissue margin, biopsy

- No tumor seen.

Clinical History:

T3 squamous cell carcinoma of larynx.

Gross Description:

Container A received fresh for frozen section is a 4.0 x 3.0 x 1.8 cm red-tan soft tissue fragment entirely submitted in FSA1, [REDACTED]

Container B received fresh for frozen section is a 5.0 x 0.5 x 0.3 cm red-tan soft tissue fragment entirely submitted in FSB1, [REDACTED]

Container C received fresh for frozen section is a 2.0 x 1.0 x 0.5 cm red-tan soft tissue fragment entirely submitted in FSC1, [REDACTED]

Container D received fresh for frozen section is a 2.0 x 1.5 x 0.7 cm red-tan soft tissue fragment entirely submitted in FSD1, [REDACTED]

Container E is additionally labeled "right Level 2A lymph nodes." It holds a 2.8 x 1.6 x 0.6 cm pink/tan lymph node packet. Three possible lymph node candidates are entirely submitted in block E1, [REDACTED]

Container F is additionally labeled "right supraclavicular lymph nodes." It holds a 1.2 x 0.9 x 0.3 cm tan/pink lymph node packet with two lymph node candidates entirely submitted in block F1, [REDACTED]

Container G is additionally labeled "Level 2 right neck node." It holds a 4.6 x 3.7 x 0.9 cm pink/tan lymph node packet with at least three lymph node candidates. The largest (G1) measures 2.6 x 1.5 x 1.0 cm.

Block summary:

G1 - one lymph node candidate, bisected

G2 - one lymph node candidate, bisected

G3 - one large lymph node candidate, bisected with two small additional lymph node candidates; fibrovascular tissue remains.

Container H is additionally labeled "Level 3, right neck node." It holds a 4.2 x 3.9 x 0.7 cm pink/tan packet with multiple lymph node candidates and fibroadipose tissue.

[page 3 of 4]
Block summary:

H1 - four lymph node candidates
H2 - two lymph node candidates
H3 - four lymph node candidates
H4 - three lymph node candidates

Container I is additionally labeled "Level 1, right neck node." It holds a 3.6 x 3.3 x 0.5 cm packet of yellow/pink fibroadipose tissue with lymph node candidates.

Block summary:

I1 - one large lymph node candidate, bisected and a single small lymph node
I2 - three lymph node candidates
I3 - remaining fibrovascular tissue
Entire specimen submitted, [REDACTED]

Container J is additionally labeled "Left Level 1B lymph node." It holds a 2.9 x 2.0 x 0.5 cm packet of yellow/pink fibroadipose tissue with lymph node candidates. The specimen is entirely submitted in block J1, [REDACTED]

Container K is additionally labeled "left Level 2A and 3." It holds a 4.8 x 4.1 x 1.3 cm packet of purple/pink lymph node candidates, the largest measures 2.6 x 1.5 x 0.8 cm.

Block summary:

K1 - one lymph node candidate, bisected
K2 - one grossly positive node, bisected with a single adjacent small node
K3 - two lymph node candidates, grossly adherent to each other, bisected
K4 - one lymph node candidate, bisected
K5 - four lymph node candidates
K6 - remaining fibroadipose tissue, [REDACTED]

Container L is additionally labeled "left Level 2B." It holds a 2.4 x 1.8 x 0.6 cm packet of yellow/pink fibroadipose tissue with lymph node candidates. Entirely submitted in blocks L1 and L2, [REDACTED]

Container M is additionally labeled "left Level 3." It holds a 2.9 x 2.4 x 0.7 cm packet of yellow/tan fibroadipose tissue with lymph node candidates.

Block Summary:

M1 - three lymph node candidates
M2 - two lymph node candidates
M3 - three lymph node candidates
Entire specimen submitted.

Container N is additionally labeled "left Level 4 lymph node." It holds a 3.4 x 2.5 x 0.8 cm yellow/pink lymph node packet.

Block summary:

N1 - one lymph node candidate, bisected
N2 - three lymph node candidates, submitted with remaining fibroadipose tissue
Entire specimen submitted.

Container O:

Specimen fixation: formalin

Type of specimen: total laryngectomy, thyroidectomy

Size of specimen: 10.5 x 6.8 x 3.8 cm

Orientation of specimen: The thyroid outer surface is inked blue, the anterior soft tissue margin is inked black.

Tumor description: white/tan, firm mass located at the right aryepiglottic fold extending into the pyriform sinus

Location of tumor: right supraglottic region in the right aryepiglottic folds extending into the pyriform region

Tumor size: 2.7 x 2.6 x 1.7 cm

Extent of tumor: Tumor extends from the right supraglottic region in the right aryepiglottic folds and extending into the pyriform region.

[page 4 of 4]
Distance of tumor from surgical margins: 0.5 cm from right epiglottic fold mucosal margin, 4.6 cm from the tracheal margin, 4.3 cm from the right superior soft tissue margin

Description of remainder of tissue: The left aryepiglottic fold is grossly normal and uninvolved. The vocal cords are not grossly involved. The anterior soft tissue margin is not grossly involved. The left lateral soft tissue margin is not involved.

Tissue submitted for special investigations: yes; For tissue procurement.

Lymph nodes: per block summary

Digital photograph taken: no

Block summary:

(Inking: right thyroid=blue, anterior soft tissue=black)

O1 - tracheal ring margin, en face

O2 - tumor with right aryepiglottic fold with tumor mucosal margin

O3 - right epiglottis

O4,O5 - section of tumor at right aryepiglottic fold extending from pyriformis from superficial to deep

O6,O7 - additional section of tumor, bisected, superficial to deep

O8 - right vocal cord

O9 - mid vocal cord

O10 - left vocal cord

O11 - left aryepiglottic fold and pyriform sinus

O12 - anterior soft tissue margin, en face

O13 - anterior soft tissue margin (right anterolateral, 2.2 cm from main tumor, en face)

O14,O15 additional section of mass, superficial to deep

O16 - representative section of thyroid

O17,O18 - sections of grossly uninvolved thyroid cartilage underlying mass

Container P is additionally labeled "right base of tongue resection." It holds a 3.1 x 2.2 x 0.7 cm tan/pink soft tissue fragment. The specimen is sectioned and entirely submitted in blocks P1 and P2, [REDACTED]

Light Microscopy:

Light microscopic examination is performed by Dr.

Signature

Resident Physician: Attending Pathologist:

I have personally conducted the evaluation of the above specimens and have rendered the above diagnosis(es).

Source: NCI Genomic Data Commons file c00a751c-4a7e-4499-a5c1-06b816ec8b8d (TCGA-BA-5555.DCBCF3A2-97E7-49BD-9E52-AE2ABF52111E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).